Somatic mutation profile of tumor specimen C3L-00088-01 (aliquot CPT0000870012) from CPTAC case C3L-00088, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 72.6 years (26,509 days).
Specimen C3L-00088-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0dfdf7a-961c-4d41-bcc3-f8ec52ebff69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00088-31 (Blood Derived Normal), aliquot CPT0003890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64e8c3a2-fb4d-4317-8d88-93a6b8346f97

The open-access MAF lists 135 somatic variants for this specimen: 94 protein-altering or splice-affecting, 31 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 31, Frame Shift Del 8, Intron 7, Nonsense Mutation 4, Frame Shift Ins 2, In Frame Del 2, Splice Region 2, RNA 1, 3'UTR 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 75/267 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs5030807, CM941368, COSV56543066, COSV56543312, COSV56543561; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.504G>T p.M168I | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV67131184; called by muse, mutect2, varscan2
- ARID1B | c.1975C>T p.Q659* | Nonsense Mutation (SNP) | VAF 33/125 reads (26%) | catalogued as rs1554270831, COSV51652422; called by muse, mutect2, varscan2
- ATP6V0A4 | c.524G>C p.G175A | Missense Mutation (SNP) | VAF 102/416 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM023018; called by muse, mutect2, varscan2
- C4orf33 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 73/287 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749633073; called by muse, mutect2, varscan2
- CNTNAP2 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs751589771, COSV62182713; called by muse, mutect2
- CUL9 | c.671A>G p.Y224C | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs369512270; called by muse, mutect2, varscan2
- DCP1B | c.1272del p.E425Nfs*22 | Frame Shift Del (DEL) | VAF 37/156 reads (24%) | catalogued as rs987194464; called by mutect2, pindel, varscan2
- DGKK | c.1311G>A p.V437= | Splice Region (SNP) | VAF 16/82 reads (20%) | catalogued as rs1557226585; called by muse, mutect2, varscan2
- FAM89A | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs980772507; called by muse, mutect2, varscan2
- GNAS | c.205G>T p.G69* | Nonsense Mutation (SNP) | VAF 63/292 reads (22%) | catalogued as COSV58335334; called by muse, mutect2, varscan2
- GPR84 | c.1112C>G p.A371G | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57209724; called by muse, mutect2, varscan2
- HADHA | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 122/383 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs1308038961, COSV66108310; called by muse, mutect2, varscan2
- HIP1R | c.3136G>T p.V1046L | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53440202; called by muse, mutect2, varscan2
- HUS1 | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as rs1562590048; called by muse, mutect2, varscan2
- KRT6A | c.13T>G p.S5A | Missense Mutation (SNP) | VAF 122/531 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV58105962; called by muse, mutect2, varscan2
- LRFN5 | c.1642C>A p.L548M | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV53255336, COSV99983736; called by muse, mutect2
- LRRC28 | c.238G>T p.V80F | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV57337232; called by muse, mutect2, varscan2
- LRRC47 | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as rs186336583; called by muse, mutect2, varscan2
- LYST | c.1654G>C p.V552L | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs770087096; called by muse, mutect2, varscan2
- NRN1L | c.62T>C p.L21S | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs1443175766; called by muse, mutect2, varscan2
- RPAP1 | c.3214G>A p.A1072T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1371939972; called by muse, mutect2, varscan2
- RPRD2 | c.493A>G p.K165E | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.014); catalogued as rs1279619569; called by muse, mutect2, varscan2
- STEAP4 | c.340C>G p.P114A | Missense Mutation (SNP) | VAF 79/326 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.139); catalogued as COSV100112362; called by muse, mutect2, varscan2
- TMEM67 | c.182C>G p.S61W | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs746906232, COSV100019749; called by muse, mutect2, varscan2
- TRRAP | c.6205A>G p.S2069G (on ENST00000359863 / NM_001244580.1; = p.S2051G on NM_003496.3) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1245759325; called by muse, mutect2
- ZNF727 | c.565A>G p.I189V | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs778482677; called by muse, mutect2, varscan2
- ZNF729 | c.283T>C p.W95R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.844); catalogued as rs756153219; called by muse, varscan2
- AC004922.1 | c.1715T>A p.L572Q | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- AC006059.2 | c.1633del p.S545Pfs*139 | Frame Shift Del (DEL) | VAF 28/119 reads (24%) | called by mutect2, pindel, varscan2
- ALKBH4 | c.655A>T p.I219L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMELX | c.295_296insAAAC p.P99Qfs*76 | Frame Shift Ins (INS) | VAF 69/151 reads (46%) | called by mutect2, pindel, varscan2
- ANKRD26 | c.1633C>G p.Q545E | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ANKRD31 | c.2110A>G p.I704V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP12A | c.1812G>T p.L604F | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); called by muse, varscan2
- CLCA1 | c.509dup p.N170Kfs*2 | Frame Shift Ins (INS) | VAF 28/157 reads (18%) | called by mutect2, pindel, varscan2
- COL27A1 | c.4787A>G p.D1596G | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- CRYBA1 | c.458G>A p.W153* | Nonsense Mutation (SNP) | VAF 51/240 reads (21%) | called by muse, mutect2, varscan2
- DZIP1 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- EIF2B2 | c.589T>G p.F197V | Missense Mutation (SNP) | VAF 84/362 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- FAT2 | c.8430_8434del p.M2810Ifs*12 | Frame Shift Del (DEL) | VAF 44/257 reads (17%) | called by mutect2, pindel, varscan2
- FKBP15 | c.2576A>G p.N859S | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FLYWCH1 | c.815A>T p.E272V (on ENST00000253928 / NM_001308068.2; = p.E271V on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- FREM3 | c.2311C>G p.L771V | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GANAB | c.2726-2A>T p.X909_splice | Splice Site (SNP) | VAF 39/178 reads (22%) | called by muse, mutect2, varscan2
- GKAP1 | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- GNS | c.1368G>T p.R456S | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR89A | c.1204A>G p.M402V | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- GRM1 | c.2183A>G p.E728G | Missense Mutation (SNP) | VAF 73/293 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HELB | c.1396T>C p.C466R | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HES2 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- HOOK2 | c.1523A>T p.Q508L | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- HP | c.867T>A p.N289K | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- IGHG2 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ISYNA1 | c.841C>G p.Q281E | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KCNC4 | c.779T>C p.I260T | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- KPNA5 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT84 | c.1365G>C p.K455N | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP4-12 | c.541T>A p.Y181N | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- LTBP2 | c.3140A>G p.K1047R | Missense Mutation (SNP) | VAF 83/354 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- LYSMD2 | c.559A>C p.I187L | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAP3K1 | c.2927_2933del p.S976* | Frame Shift Del (DEL) | VAF 35/172 reads (20%) | called by mutect2, pindel, varscan2
- MUC16 | c.10969A>G p.S3657G | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH6 | c.2209T>C p.F737L | Missense Mutation (SNP) | VAF 107/444 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NBEA | c.1790del p.H597Pfs*41 | Frame Shift Del (DEL) | VAF 33/127 reads (26%) | called by mutect2, pindel, varscan2
- NECTIN2 | c.598C>G p.L200V | Missense Mutation (SNP) | VAF 72/341 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- NME8 | c.955T>A p.L319M | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); called by muse, mutect2
- OR10A3 | c.825_836del p.A277_L280del | In Frame Del (DEL) | VAF 22/214 reads (10%) | called by mutect2, pindel
- PARP10 | c.2819A>C p.H940P | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PDE4DIP | c.3865C>G p.R1289G | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PDK2 | c.72_74del p.S24_K25delinsR | In Frame Del (DEL) | VAF 34/145 reads (23%) | called by mutect2, pindel, varscan2
- PHTF1 | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.054); called by muse, varscan2
- POMGNT1 | c.1774C>A p.Q592K | Missense Mutation (SNP) | VAF 29/146 reads (20%) | PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PRX | c.1193T>A p.L398H | Missense Mutation (SNP) | VAF 65/263 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RANBP9 | c.1163C>G p.A388G | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RGS5 | c.216C>G p.N72K | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIT1 | c.11G>C p.G4A | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROCK2 | c.675del p.H225Qfs*4 | Frame Shift Del (DEL) | VAF 37/148 reads (25%) | called by mutect2, pindel, varscan2
- SESN1 | c.1198A>T p.M400L (on ENST00000356644 / NM_001199933.1; = p.M459L on NM_014454.3) | Missense Mutation (SNP) | VAF 63/321 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SOGA1 | c.1662_1680del p.D554Efs*97 | Frame Shift Del (DEL) | VAF 43/150 reads (29%) | called by mutect2, pindel, varscan2
- SOS2 | c.2392C>G p.Q798E | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPG11 | c.4111T>A p.W1371R | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SRCAP | c.5717A>T p.Q1906L | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SVEP1 | c.164A>G p.E55G | Missense Mutation (SNP) | VAF 65/281 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TACSTD2 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 10/265 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); called by muse, mutect2
- TAF4 | c.2373C>A p.V791= | Splice Region (SNP) | VAF 43/136 reads (32%) | called by muse, mutect2, varscan2
- TCF7L2 | c.21_27del p.G8Mfs*3 | Frame Shift Del (DEL) | VAF 44/202 reads (22%) | called by mutect2, pindel, varscan2
- TMCO1 | c.132A>C p.R44S | Missense Mutation (SNP) | VAF 83/313 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM132C | c.1271A>T p.Q424L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, mutect2
- TMEM87A | c.125G>A p.W42* | Nonsense Mutation (SNP) | VAF 28/104 reads (27%) | called by muse, mutect2, varscan2
- VCL | c.1744G>A p.D582N | Missense Mutation (SNP) | VAF 72/314 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- XKR6 | c.1712C>G p.P571R | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF679 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ZSCAN21 | c.775T>C p.S259P | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAM2 | c.9C>T p.R3= | Silent (SNP) | VAF 44/206 reads (21%) | catalogued as rs549926110, COSV55866557; called by muse, mutect2, varscan2
- ARVCF | c.2445G>C p.S815= | Silent (SNP) | VAF 43/160 reads (27%) | called by muse, mutect2, varscan2
- BIRC6 | c.10533T>C p.Y3511= | Silent (SNP) | VAF 57/216 reads (26%) | catalogued as rs1242611428; called by muse, mutect2, varscan2
- BMP6 | c.993G>C p.V331= | Silent (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- CCM2 | c.1167G>A p.R389= | Silent (SNP) | VAF 116/455 reads (25%) | called by muse, mutect2, varscan2
- CELSR1 | c.7770C>T p.V2590= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as rs867720885; called by muse, mutect2, varscan2
- CLCN3 | c.1077T>G p.A359= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV61626111; called by muse, mutect2
- COL24A1 | c.579A>G p.E193= | Silent (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- COL9A3 | c.444C>A p.G148= | Silent (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
- DGKK | c.3312C>G p.V1104= | Silent (SNP) | VAF 38/60 reads (63%) | called by muse, mutect2, varscan2
- DYNC1I1 | c.636T>A p.P212= | Silent (SNP) | VAF 34/128 reads (27%) | called by muse, varscan2
- FBN3 | c.2985C>T p.G995= | Silent (SNP) | VAF 45/157 reads (29%) | catalogued as rs1409742798; called by muse, mutect2, varscan2
- GRIP1 | c.132C>T p.I44= | Silent (SNP) | VAF 76/350 reads (22%) | called by muse, mutect2, varscan2
- LINGO1 | c.303G>A p.E101= | Silent (SNP) | VAF 32/147 reads (22%) | called by muse, mutect2, varscan2
- LRIG1 | c.2370G>A p.G790= | Silent (SNP) | VAF 32/98 reads (33%) | called by muse, mutect2, varscan2
- MED15 | c.2172T>C p.S724= (on ENST00000263205 / NM_001003891.3; = p.S684= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/211 reads (22%) | called by muse, mutect2, varscan2
- NCAPG2 | c.2490C>A p.I830= | Silent (SNP) | VAF 52/180 reads (29%) | called by muse, mutect2, varscan2
- PFKFB1 | c.687G>T p.V229= | Silent (SNP) | VAF 56/106 reads (53%) | called by muse, mutect2, varscan2
- RNF213 | c.6246A>T p.I2082= | Silent (SNP) | VAF 80/317 reads (25%) | called by muse, mutect2, varscan2
- SEPTIN14 | c.642A>G p.E214= | Silent (SNP) | VAF 38/167 reads (23%) | catalogued as rs1424432316, COSV66428300; called by muse, mutect2, varscan2
- SERTM1 | c.231A>G p.P77= | Silent (SNP) | VAF 33/175 reads (19%) | called by muse, mutect2, varscan2
- SETD2 | c.4932A>T p.G1644= | Silent (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- SEZ6L2 | c.348C>A p.G116= | Silent (SNP) | VAF 30/126 reads (24%) | called by muse, mutect2, varscan2
- SLC39A4 | c.15C>A p.V5= | Silent (SNP) | VAF 27/310 reads (9%) | called by muse, mutect2
- SRRM5 | c.717A>G p.S239= | Silent (SNP) | VAF 53/243 reads (22%) | called by muse, mutect2, varscan2
- TIGD4 | c.1371G>A p.E457= | Silent (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- TMEM200A | c.795T>C p.T265= | Silent (SNP) | VAF 25/112 reads (22%) | called by muse, mutect2, varscan2
- TSC22D1 | c.2826T>C p.S942= | Silent (SNP) | VAF 48/176 reads (27%) | called by muse, mutect2, varscan2
- TTYH3 | c.516G>A p.Q172= | Silent (SNP) | VAF 29/151 reads (19%) | called by muse, mutect2, varscan2
- UBXN1 | c.588T>C p.P196= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as COSV53656968; called by muse, mutect2, varscan2
- ZNF41 | c.309G>T p.G103= | Silent (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- ACSS2 | chr20:34875098 AAATGATGG>T | 5'Flank (DEL) | VAF 45/197 reads (23%) | called by pindel, varscan2*
- CELF2 | c.53+12611A>G | Intron (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- INPP4A | c.151+21T>G | Intron (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- MIR146A | n.21dup | RNA (INS) | VAF 76/223 reads (34%) | called by mutect2, pindel, varscan2
- MYOZ3 | c.425-139G>A | Intron (SNP) | VAF 123/334 reads (37%) | catalogued as rs1426695257; called by muse, mutect2, varscan2
- RBKS | c.90-12247T>G | Intron (SNP) | VAF 14/121 reads (12%) | called by muse, mutect2, varscan2
- SLC4A2 | c.3048-163G>A | Intron (SNP) | VAF 22/64 reads (34%) | catalogued as rs1040761454; called by muse, mutect2, varscan2
- SLC4A4 | c.1903+75del | Intron (DEL) | VAF 54/229 reads (24%) | called by mutect2, pindel, varscan2
- ZNF407 | c.4877+22484A>G | Intron (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- ZWINT | c.*81_*82del | 3'UTR (DEL) | VAF 50/231 reads (22%) | called by mutect2, pindel, varscan2
